CMI case ASCProject_0064 — CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/785da20f-3e1e-42dc-9323-6f53595c530e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Angiosarcoma: Tissue or organ of origin: Head, face or neck, NOS; Site of resection or biopsy: Head, face or neck, NOS; Age at diagnosis: 32.7 years (11,942 days).

Biospecimens (3 samples)
- Sample ASCProject_0064_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Sample ASCProject_0064_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Forehead; Preservation method: FFPE.
- Sample ASCProject_0064_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: FFPE.
